CCDI case PBBNBW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/c5e409cf-d59e-4033-977b-64fe64dc4350

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 8.9 years (3,259 days).

Biospecimens (3 samples)
- Sample 0DDDTO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDDTP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DDDTQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
